Gene-level copy-number profile of tumor specimen C3L-10231-03 from CPTAC case C3L-10231, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,177 days).
Specimen C3L-10231-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 873eb155-6e81-4b46-a1a5-8214d600288f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-10231-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/5d09cf2a-b8b2-4eb2-aa35-f13dc02b497e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 16,051; copy number 2: 40,027; copy number 3: 2,301.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,560,047–18,568,790, 2 genes (within-gene range 0–2): CR383656.7, CR383656.13.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–1): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr18:36,829,106–37,232,172, 2 genes (within-gene range 0–1): KIAA1328, AC016493.1.
- chr18:50,959,267–51,688,209, 12 genes: Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,707. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
